Somatic mutation profile of tumor specimen TCGA-34-2600-01A (aliquot TCGA-34-2600-01A-01D-1522-08) from TCGA case TCGA-34-2600, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.9 years (28,072 days).
Specimen TCGA-34-2600-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27c79473-99da-4065-90e8-1131a92474db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2600-11A (Solid Tissue Normal), aliquot TCGA-34-2600-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79aaf2f1-7fdc-40b6-ae06-b94f4a56f98b

The open-access MAF lists 439 somatic variants for this specimen: 332 protein-altering or splice-affecting, 98 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 283, Silent 98, Nonsense Mutation 31, Splice Site 8, Intron 7, Frame Shift Del 5, Splice Region 4, Frame Shift Ins 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRX | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs863224863, CM113154, COSV55759682; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.939+1169C>G | Intron (SNP) | VAF 15/139 reads (11%) | catalogued as rs1057519791, COSV100336065; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 26/103 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 18/26 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSL6 | c.2012C>A p.T671K (on ENST00000379240; = p.T696K on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/74 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57303276; called by muse, mutect2, varscan2
- ACTG2 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as rs747982211, COSV61829328; called by muse, mutect2, varscan2
- ADAM18 | c.1766C>G p.S589* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV55846746, COSV55852491; called by muse, mutect2, varscan2
- ADAM21 | c.1299T>A p.C433* | Nonsense Mutation (SNP) | VAF 106/119 reads (89%) | catalogued as COSV50804005; called by muse, mutect2, varscan2
- ADCY8 | c.2595G>A p.M865I | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs267601770, COSV53921426; called by muse, mutect2, varscan2
- ADGRA3 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 123/150 reads (82%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.535); catalogued as rs746516223, COSV51562557; called by muse, mutect2, varscan2
- ADGRG4 | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV54963843; called by muse, mutect2
- AK9 | c.2926C>T p.H976Y | Missense Mutation (SNP) | VAF 202/235 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV58147808; called by muse, mutect2, varscan2
- AL031681.2 | c.3092G>C p.R1031T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV64229388; called by muse, mutect2
- ALDH1B1 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 177/238 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV66620449; called by muse, mutect2, varscan2
- ALMS1 | c.11705C>T p.T3902I | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52518353; called by muse, mutect2, varscan2
- AMER3 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776499369, COSV58469046; called by muse, mutect2, varscan2
- ANXA1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 75/153 reads (49%) | catalogued as COSV57412286; called by muse, mutect2, varscan2
- ANXA5 | c.908A>T p.D303V | Missense Mutation (SNP) | VAF 74/92 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56639820; called by muse, mutect2, varscan2
- APOB | c.7819C>G p.L2607V | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV51947300; called by muse, mutect2, varscan2
- APOB | c.3323G>A p.G1108D | Missense Mutation (SNP) | VAF 77/116 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763870199, COSV51947314; called by muse, mutect2, varscan2
- ARHGEF9 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV53642540; called by muse, mutect2, varscan2
- ARID4B | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV51608987; called by muse, mutect2
- ARMCX5 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 51/76 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV55767284; called by muse, mutect2, varscan2
- ASPM | c.6102G>T p.M2034I | Missense Mutation (SNP) | VAF 56/462 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV54135882; called by muse, mutect2, varscan2
- ASTN2 | c.3486C>A p.D1162E (on ENST00000313400 / NM_001365069.1; = p.D1111E on NM_014010.5) | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56011913; called by muse, mutect2, varscan2
- ATP10A | c.3449T>A p.L1150Q | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63521659; called by muse, mutect2, varscan2
- ATP10D | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.085); catalogued as COSV56711565; called by muse, mutect2
- ATP13A1 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV52289971; called by muse, mutect2, varscan2
- ATP1B4 | c.670C>A p.R224S (on ENST00000218008 / NM_001142447.3; = p.R220S on NM_012069.5) | Missense Mutation (SNP) | VAF 192/311 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54314349, COSV54314984; called by muse, mutect2, varscan2
- AXDND1 | c.2767G>T p.A923S | Missense Mutation (SNP) | VAF 107/233 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV62646674; called by muse, mutect2, varscan2
- BAZ1A | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 65/80 reads (81%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV62411738; called by muse, mutect2, varscan2
- BHLHE22 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs1257035127, COSV58862546; called by muse, mutect2, varscan2
- BRD9 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51321422; called by muse, mutect2, varscan2
- C11orf58 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV57179068; called by muse, mutect2, varscan2
- C16orf46 | c.1042G>T p.V348L | Missense Mutation (SNP) | VAF 89/241 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs575984281, COSV55152463; called by muse, mutect2, varscan2
- C2CD6 | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53798850; called by muse, mutect2, varscan2
- C2orf78 | c.1378T>G p.L460V | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV68518821; called by muse, mutect2, varscan2
- C6 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 181/496 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54715678; called by muse, mutect2, varscan2
- CA12 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51607407; called by muse, mutect2, varscan2
- CACNA2D1 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs779648475, COSV62375013, COSV62388706; called by muse, mutect2, varscan2
- CAMK4 | c.1310C>G p.A437G | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV56679436; called by muse, mutect2
- CAND1 | c.2922G>C p.L974F | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV73389737; called by muse, mutect2
- CAND1 | c.3218A>T p.H1073L | Missense Mutation (SNP) | VAF 171/302 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV73389738; called by muse, mutect2, varscan2
- CAPN15 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350975135, COSV54834557; called by muse, mutect2, varscan2
- CBFB | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV52000399; called by muse, varscan2
- CBFB | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52000409; called by muse, varscan2
- CBLN2 | c.437G>C p.S146T | Missense Mutation (SNP) | VAF 154/316 reads (49%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.489); catalogued as COSV54052558; called by muse, mutect2, varscan2
- CCDC6 | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54059171; called by muse, mutect2, varscan2
- CCDC96 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 347/429 reads (81%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV59509207; called by muse, mutect2, varscan2
- CCNE2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 153/288 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV57377131; called by muse, mutect2, varscan2
- CD109 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54654865; called by muse, mutect2
- CD1B | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 133/303 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63804594, COSV63804943; called by muse, mutect2, varscan2
- CD99L2 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 54/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57988401; called by muse, mutect2, varscan2
- CDH18 | c.665A>T p.H222L | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV104386327, COSV56949716; called by muse, mutect2, varscan2
- CDH9 | c.347T>A p.L116Q | Missense Mutation (SNP) | VAF 174/489 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50384163; called by muse, mutect2, varscan2
- CDR1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 111/360 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868811042, COSV65164314; called by muse, mutect2, varscan2
- CENPE | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs889930003, COSV54387273; called by muse, mutect2
- CENPJ | c.3750G>C p.Q1250H | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV55047851; called by muse, mutect2
- CFAP44 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 14/382 reads (4%) | catalogued as COSV55614704; called by muse, mutect2
- CFHR2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as rs370528458, COSV66381914; called by muse, mutect2, varscan2
- CGB7 | c.384G>C p.L128F | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as rs776569449, COSV100655035, COSV62281759; called by muse, mutect2, varscan2
- CLVS2 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 118/132 reads (89%) | catalogued as rs767545171, COSV51567651; called by muse, mutect2, varscan2
- CNKSR2 | c.1656A>C p.K552N | Missense Mutation (SNP) | VAF 70/100 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV54263500; called by muse, mutect2, varscan2
- COBLL1 | c.2677G>A p.D893N (on ENST00000392717; = p.D855N on NM_014900.5) | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52073695; called by muse, mutect2
- COL13A1 | c.765A>C p.K255N (on ENST00000398978 / NM_001130103.2; = p.K198N on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.651); catalogued as COSV62573429; called by muse, varscan2
- COL15A1 | c.3922G>C p.D1308H | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66648126; called by muse, mutect2, varscan2
- COL3A1 | c.1762-1G>T p.X588_splice | Splice Site (SNP) | VAF 47/204 reads (23%) | catalogued as COSV58591126, COSV58594445; called by muse, mutect2, varscan2
- COL6A6 | c.5485G>A p.E1829K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV62033638; called by muse, mutect2
- COMMD8 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as COSV67500677; called by muse, mutect2, varscan2
- COPB2 | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60813568; called by muse, mutect2
- CORO7 | c.946C>G p.P316A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52032972; called by muse, mutect2, varscan2
- CPT1A | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT tolerated (0.32); PolyPhen benign (0.091); catalogued as COSV55759628; called by muse, mutect2, varscan2
- CREBBP | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 49/149 reads (33%) | catalogued as COSV52135898; called by muse, mutect2, varscan2
- CSMD2 | c.4036G>T p.A1346S | Missense Mutation (SNP) | VAF 106/326 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV53946584; called by muse, mutect2, varscan2
- CSNK1A1L | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65790031; called by muse, mutect2, varscan2
- CTDSP1 | c.472-2A>T p.X158_splice | Splice Site (SNP) | VAF 42/151 reads (28%) | catalogued as COSV56090487; called by muse, mutect2, varscan2
- CTSK | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 72/279 reads (26%) | catalogued as COSV55013389; called by muse, mutect2, varscan2
- CTTNBP2 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50448602; called by muse, mutect2, varscan2
- CUX1 | c.1108G>A p.E370K (on ENST00000292535 / NM_181552.4; = p.E381K on NM_001913.5) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.16); catalogued as rs782320090, COSV52910563; called by muse, mutect2, varscan2
- DECR2 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV54795895; called by muse, mutect2, varscan2
- DEFB110 | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV64484788; called by muse, mutect2, varscan2
- DGKK | c.2100A>G p.I700M | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV65709070; called by muse, mutect2, varscan2
- DMXL2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756757123, COSV51853176; called by muse, mutect2, varscan2
- DNAH11 | c.4360G>C p.E1454Q | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs985818251, COSV60973258; called by muse, mutect2, varscan2
- DNAH5 | c.9161C>G p.S3054* | Nonsense Mutation (SNP) | VAF 83/280 reads (30%) | catalogued as COSV54244447; called by muse, mutect2, varscan2
- DNAH9 | c.2032C>G p.L678V | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52368777; called by muse, mutect2
- DNAJB5 | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 91/110 reads (83%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV56626561, COSV56627032; called by muse, mutect2, varscan2
- DOCK3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV56541431; called by muse, mutect2, varscan2
- DPP9 | c.490G>T p.D164Y (on ENST00000598800; = p.D193Y on NM_139159.5) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53590008, COSV53593505; called by muse, mutect2
- DSG4 | c.2557G>T p.E853* | Nonsense Mutation (SNP) | VAF 177/300 reads (59%) | catalogued as COSV57396040; called by muse, mutect2, varscan2
- DUOXA2 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50994409; called by muse, mutect2
- EFCAB6 | c.4039G>T p.D1347Y | Missense Mutation (SNP) | VAF 123/261 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV53069566; called by muse, mutect2, varscan2
- EHBP1 | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 22/209 reads (11%) | catalogued as rs1400945328, COSV50430888; called by muse, varscan2
- ELOF1 | c.188-1G>C p.X63_splice | Splice Site (SNP) | VAF 20/89 reads (22%) | catalogued as COSV99370640; called by muse, mutect2, varscan2
- EPHB6 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs756409968, COSV67420296; called by muse, mutect2, varscan2
- ERBB2 | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1393814915, COSV54078707; called by muse, mutect2, varscan2
- EYA4 | c.581-1G>C p.X194_splice | Splice Site (SNP) | VAF 26/113 reads (23%) | catalogued as COSV100765069, COSV62058516; called by muse, mutect2, varscan2
- F5 | c.4168G>C p.E1390Q | Missense Mutation (SNP) | VAF 167/365 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV63125502; called by muse, mutect2, varscan2
- FAM135B | c.4156G>C p.V1386L | Missense Mutation (SNP) | VAF 138/370 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs764651487, COSV52730852, COSV52745568; called by muse, mutect2, varscan2
- FAM135B | c.3253G>A p.D1085N | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV52745589, COSV52748374; called by muse, mutect2, varscan2
- FAM135B | c.1462A>T p.T488S | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV52745603; called by muse, mutect2, varscan2
- FAM163A | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.92); catalogued as COSV59205174; called by muse, mutect2
- FARP2 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1172435178, COSV50877786; called by muse, mutect2
- FCRL4 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.132); catalogued as COSV54864946; called by muse, mutect2
- FEZF2 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV51864154; called by muse, mutect2, varscan2
- FGD1 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV64309379; called by muse, mutect2, varscan2
- FHL3 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65952781; called by muse, mutect2
- FLG2 | c.5926C>G p.H1976D | Missense Mutation (SNP) | VAF 215/756 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV66170706, COSV66171646; called by muse, mutect2, varscan2
- FLG2 | c.4085G>A p.R1362K | Missense Mutation (SNP) | VAF 172/425 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV66171653; called by muse, mutect2, varscan2
- FLT3 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 92/420 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as COSV54048059; called by muse, mutect2, varscan2
- FMR1NB | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 136/246 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV65072800; called by muse, mutect2, varscan2
- FSCB | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 131/168 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV61219215; called by muse, mutect2, varscan2
- GABRA4 | c.1289C>A p.A430D | Missense Mutation (SNP) | VAF 81/119 reads (68%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV51933128; called by muse, mutect2, varscan2
- GFOD1 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV64953351; called by muse, mutect2, varscan2
- GJC1 | c.627C>G p.C209W | Missense Mutation (SNP) | VAF 150/184 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57912407; called by muse, mutect2, varscan2
- GJC1 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 152/186 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57912418; called by muse, mutect2, varscan2
- GLUD2 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV60152768; called by muse, mutect2
- GOLIM4 | c.1176G>A p.E392= | Splice Region (SNP) | VAF 48/1050 reads (5%) | catalogued as rs1204579949, COSV58331332; called by muse, mutect2
- GON4L | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 135/272 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1343729486, COSV55200597; called by muse, mutect2, varscan2
- GP5 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 157/212 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV55468311; called by muse, mutect2, varscan2
- GPR137 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV57403440, COSV57404040; called by muse, varscan2
- GPR37 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV58258968; called by muse, mutect2, varscan2
- GPR37 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 12/379 reads (3%) | catalogued as COSV58258979; called by muse, mutect2
- GPRASP1 | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 87/451 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100851048, COSV64356245; called by muse, mutect2, varscan2
- GRIN2B | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as rs749839263, COSV74207229; called by muse, mutect2, varscan2
- GRM8 | c.1994C>A p.A665D | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58856325; called by muse, mutect2, varscan2
- GTDC1 | c.1135G>A p.E379K (on ENST00000344850 / NM_001354361.1; = p.E294K on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54002529; called by muse, mutect2
- H2BC7 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100587227, COSV61911476, COSV61912249; called by muse, mutect2, varscan2
- HEATR3 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV53531034; called by muse, mutect2, varscan2
- HELB | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56075425; called by muse, mutect2, varscan2
- HELB | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 180/340 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV56073807, COSV56075434; called by muse, mutect2, varscan2
- HLCS | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV60796857; called by muse, mutect2
- HNRNPD | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 46/56 reads (82%) | catalogued as COSV58314597, COSV58314717; called by muse, mutect2, varscan2
- HRNR | c.5789C>G p.S1930C | Missense Mutation (SNP) | VAF 178/2688 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV100914021, COSV64261277; called by muse, mutect2
- IDH3G | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54209404; called by muse, mutect2
- IFT140 | c.3688G>A p.D1230N | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63698914; called by muse, mutect2
- IGKV1-5 | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs182340840; called by muse, mutect2, varscan2
- IGKV6D-21 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 133/217 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs753016861; called by muse, mutect2, varscan2
- IGSF11 | c.846T>G p.N282K (on ENST00000393775 / NM_001015887.3; = p.N281K on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/548 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61176158; called by muse, mutect2, varscan2
- IL12B | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as COSV51455515; called by muse, mutect2
- IL1RAPL1 | c.1372+1G>T p.X458_splice | Splice Site (SNP) | VAF 70/260 reads (27%) | catalogued as COSV100151935, COSV56288478; called by muse, mutect2, varscan2
- IL1RAPL2 | c.980C>A p.A327E | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.587); catalogued as COSV61161110, COSV61173588; called by muse, mutect2, varscan2
- ITIH2 | c.743A>T p.H248L | Missense Mutation (SNP) | VAF 87/160 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64434657; called by muse, mutect2, varscan2
- KALRN | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53775772; called by muse, mutect2
- KAT6A | c.2996C>G p.S999* | Nonsense Mutation (SNP) | VAF 12/294 reads (4%) | catalogued as COSV55903560; called by muse, mutect2
- KBTBD7 | c.1154C>A p.S385* | Nonsense Mutation (SNP) | VAF 14/209 reads (7%) | catalogued as COSV65267008; called by muse, mutect2
- KBTBD7 | c.1041C>G p.I347M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV101068091; called by mutect2, varscan2
- KCNF1 | c.1219A>T p.N407Y | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV54464936; called by muse, mutect2, varscan2
- KDM4A | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 84/219 reads (38%) | catalogued as COSV100969371, COSV64960339; called by muse, mutect2, varscan2
- KIAA1210 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.415); catalogued as COSV68175254; called by muse, mutect2
- KIF22 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV50717391; called by muse, mutect2, varscan2
- KLHL38 | c.1565A>C p.K522T | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV58088623; called by muse, mutect2, varscan2
- KMT2C | c.5371C>T p.Q1791* | Nonsense Mutation (SNP) | VAF 234/384 reads (61%) | catalogued as COSV51427498; called by muse, mutect2, varscan2
- KNG1 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs781268489, COSV53976364, COSV53980317; called by muse, mutect2, varscan2
- LELP1 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64202674; called by muse, mutect2, varscan2
- LEO1 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 114/153 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs751561202, COSV55175183, COSV55176232; called by muse, varscan2
- LONRF3 | c.794A>T p.K265M | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV59155803; called by muse, mutect2, varscan2
- LPA | c.5015C>A p.T1672K | Missense Mutation (SNP) | VAF 127/145 reads (88%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV60307959; called by muse, mutect2, varscan2
- LRRC43 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60292235; called by muse, mutect2
- MACIR | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 73/88 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100174653, COSV60634564; called by muse, mutect2, varscan2
- MAGEA11 | c.182C>G p.P61R | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.588); catalogued as COSV60757720; called by muse, mutect2, varscan2
- MATN4 | c.1340C>A p.A447D (on ENST00000372754; = p.A406D on NM_003833.4) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | PolyPhen benign (0.02); catalogued as COSV61352414; called by muse, mutect2, varscan2
- MBTPS2 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 13/364 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as COSV63412216; called by muse, mutect2
- MBTPS2 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 189/560 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV65269809; called by muse, mutect2, varscan2
- MCF2 | c.2383G>C p.D795H | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV58492236; called by muse, mutect2, varscan2
- MCM9 | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV60165041; called by muse, mutect2
- MCTP1 | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV56528538; called by muse, mutect2, varscan2
- MICU1 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV63146994; called by muse, mutect2, varscan2
- MIER3 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 83/103 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61229961; called by muse, mutect2, varscan2
- MOG | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867181204, COSV65321620; called by muse, mutect2, varscan2
- MRPL30 | c.348G>C p.L116F | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57667513; called by muse, mutect2
- MSN | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 137/250 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64305127; called by muse, mutect2, varscan2
- MTMR14 | c.1614-1G>A p.X538_splice | Splice Site (SNP) | VAF 20/183 reads (11%) | catalogued as COSV56006836, COSV99931340; called by muse, mutect2, varscan2
- MUC16 | c.37335C>T p.L12445= | Splice Region (SNP) | VAF 7/116 reads (6%) | catalogued as COSV67484023; called by muse, mutect2
- MUC16 | c.37333C>T p.L12445F | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.998); catalogued as COSV67484026; called by muse, mutect2
- MUC16 | c.20792C>T p.S6931L | Missense Mutation (SNP) | VAF 141/512 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.281); catalogued as COSV67468635, COSV67478991; called by muse, mutect2, varscan2
- MUC17 | c.11787C>G p.I3929M | Missense Mutation (SNP) | VAF 80/303 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.854); catalogued as COSV60288339, COSV60299116; called by muse, mutect2, varscan2
- MUC2 | c.2915C>T p.S972F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); catalogued as rs755910410; called by muse, mutect2, varscan2
- MYH2 | c.3453G>T p.E1151D | Missense Mutation (SNP) | VAF 132/164 reads (80%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.927); catalogued as COSV55445437; called by muse, varscan2
- MYO5B | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 88/146 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53211787; called by muse, mutect2, varscan2
- MYO6 | c.1775A>T p.Q592L | Missense Mutation (SNP) | VAF 72/79 reads (91%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV64120661; called by muse, mutect2, varscan2
- MYT1L | c.2871C>A p.C957* | Nonsense Mutation (SNP) | VAF 61/119 reads (51%) | catalogued as COSV67704147; called by muse, mutect2, varscan2
- NAALADL2 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372321787, COSV69159199; called by muse, mutect2, varscan2
- NAV2 | c.2980G>A p.D994N (on ENST00000396087 / NM_001244963.2; = p.D971N on NM_145117.5) | Missense Mutation (SNP) | VAF 94/119 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60663487; called by muse, mutect2, varscan2
- NAV3 | c.1852C>G p.Q618E | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57103325; called by muse, mutect2, varscan2
- NBPF11 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); catalogued as rs1378510787; called by muse, mutect2
- NLGN2 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 63/76 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV57211518; called by muse, mutect2, varscan2
- NOM1 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 74/123 reads (60%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as rs757961293, COSV51980301; called by muse, mutect2, varscan2
- NOX3 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs1416844681, COSV50159861; called by muse, mutect2, varscan2
- NPC1L1 | c.2945C>T p.S982L | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs757331689, COSV56928916; called by muse, mutect2, varscan2
- NPTX1 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60776091; called by muse, mutect2, varscan2
- NR0B1 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV66764548; called by muse, mutect2, varscan2
- NTRK3 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1305137414, COSV58136865; called by muse, mutect2, varscan2
- OPLAH | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs781812234, COSV70677470; called by muse, mutect2
- OR10R2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 33/721 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1212879955, COSV63769320; called by muse, mutect2
- OR13C5 | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 13/217 reads (6%) | catalogued as COSV66165185; called by muse, mutect2
- OR2F1 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV67331870; called by muse, mutect2
- OR2G6 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 87/169 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV58575506; called by muse, mutect2, varscan2
- OR2T8 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60664219; called by muse, mutect2, varscan2
- OR4A15 | c.909A>T p.K303N | Missense Mutation (SNP) | VAF 162/193 reads (84%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as rs1565113250, COSV104406989, COSV59036908; called by muse, mutect2, varscan2
- OR51I1 | c.130A>T p.N44Y | Missense Mutation (SNP) | VAF 95/109 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66508837, COSV99061841; called by muse, mutect2, varscan2
- OR52N4 | c.503T>A p.L168Q | Missense Mutation (SNP) | VAF 175/201 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57892198; called by muse, mutect2, varscan2
- OR5F1 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 61/77 reads (79%) | catalogued as rs1302231079, COSV53548049; called by muse, mutect2, varscan2
- OR5H1 | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 8/232 reads (3%) | catalogued as COSV63403200; called by muse, mutect2
- OR8B12 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 49/65 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV104405629, COSV60912534; called by muse, mutect2, varscan2
- OR8S1 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV59600574; called by muse, mutect2, varscan2
- OTOGL | c.3403G>C p.E1135Q (on ENST00000547103; = p.E1126Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV101509181; called by muse, mutect2, varscan2
- OXLD1 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs370129678, COSV61303749; called by muse, mutect2, varscan2
- PALB2 | c.2338G>A p.G780S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55168956; called by muse, mutect2, varscan2
- PARD6G | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV62062297; called by muse, mutect2, varscan2
- PARP16 | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756333312, COSV56035523, COSV56036277; called by muse, mutect2, varscan2
- PCDH17 | c.3208C>T p.Q1070* | Nonsense Mutation (SNP) | VAF 48/188 reads (26%) | catalogued as COSV64975006; called by muse, mutect2, varscan2
- PCDHB4 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 85/109 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs782252909, COSV52025608; called by muse, mutect2, varscan2
- PCDHGC5 | c.1610G>C p.R537P | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52762923; called by muse, mutect2, varscan2
- PCSK6 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.204); catalogued as COSV61858273; called by muse, mutect2
- PDE3A | c.1729C>G p.Q577E | Missense Mutation (SNP) | VAF 94/352 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62979967; called by muse, mutect2, varscan2
- PEG3 | c.3399C>A p.C1133* | Nonsense Mutation (SNP) | VAF 215/442 reads (49%) | catalogued as COSV55643380; called by muse, mutect2, varscan2
- PIWIL2 | c.741C>T p.F247= | Splice Region (SNP) | VAF 11/66 reads (17%) | catalogued as rs1298279982, COSV63253437; called by muse, mutect2, varscan2
- PLXNB3 | c.5426A>C p.K1809T | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62796384, COSV62800796; called by muse, mutect2, varscan2
- POLR2B | c.1525G>T p.V509L | Missense Mutation (SNP) | VAF 107/130 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV58902148; called by muse, mutect2, varscan2
- PSMD3 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 131/159 reads (82%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV52859135; called by muse, mutect2, varscan2
- PTBP2 | c.469G>T p.V157F (on ENST00000426398 / NM_001300986.2; = p.V149F on NM_021190.4) | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV64626035; called by muse, mutect2, varscan2
- PTK2 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as COSV61790335; called by muse, mutect2, varscan2
- PWWP3B | c.1355A>C p.Q452P | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.892); catalogued as COSV61801172; called by muse, mutect2, varscan2
- RAB20 | c.473A>T p.Y158F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.863); catalogued as COSV57441670; called by muse, mutect2
- RAB39B | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 76/232 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65625067; called by muse, varscan2
- RABGEF1 | c.362C>T p.S121F (on ENST00000439720 / NM_001287061.2; = p.S108F on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53161746, COSV53164441; called by muse, mutect2, varscan2
- RASAL1 | c.1092C>A p.H364Q | Missense Mutation (SNP) | VAF 113/387 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55658788; called by muse, mutect2, varscan2
- RBMX | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 115/336 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV104413319, COSV57810843; called by muse, mutect2, varscan2
- RBMX | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 70/450 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV100284690, COSV57810847; called by muse, mutect2, varscan2
- RERE | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs376576951; called by muse, mutect2, varscan2
- RGS3 | c.2832G>T p.E944D (on ENST00000350696 / NM_001282923.2; = p.E663D on NM_130795.4) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV59520524; called by muse, mutect2, varscan2
- RHAG | c.641-2A>G p.X214_splice | Splice Site (SNP) | VAF 92/102 reads (90%) | catalogued as COSV57705735; called by muse, mutect2, varscan2
- RIMS1 | c.3643T>C p.S1215P | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV53475370; called by muse, mutect2, varscan2
- RNASEL | c.2072A>G p.Y691C | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62377654; called by muse, mutect2, varscan2
- RNF113A | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV65097714; called by muse, mutect2
- RNF144A | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV57984577; called by muse, mutect2
- RNPEP | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.145); catalogued as rs1393176079, COSV55243409; called by muse, mutect2
- RYR1 | c.7151T>A p.I2384N | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV62106684; called by muse, varscan2
- SAR1B | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV68391894; called by muse, mutect2, varscan2
- SCYL2 | c.2453A>G p.N818S | Missense Mutation (SNP) | VAF 217/408 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565980963, COSV62570245; called by muse, mutect2, varscan2
- SDF2 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55932206; called by muse, mutect2, varscan2
- SERBP1 | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 77/91 reads (85%) | SIFT tolerated (0.39); PolyPhen benign (0.182); catalogued as COSV63414120; called by muse, mutect2, varscan2
- SETD2 | c.7108G>T p.V2370F | Missense Mutation (SNP) | VAF 125/158 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57446958; called by muse, mutect2, varscan2
- SETDB1 | c.2462A>G p.D821G | Missense Mutation (SNP) | VAF 125/331 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54985953; called by muse, mutect2, varscan2
- SF3A1 | c.1531del p.R511Gfs*103 | Frame Shift Del (DEL) | VAF 66/203 reads (33%) | catalogued as COSV53168668; called by mutect2, varscan2
- SGO2 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63416991, COSV63418758; called by muse, mutect2
- SGO2 | c.3204G>C p.Q1068H | Missense Mutation (SNP) | VAF 145/244 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as COSV63417000; called by muse, mutect2, varscan2
- SH3KBP1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65643856; called by muse, mutect2
- SH3KBP1 | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 470/649 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV65643863; called by muse, mutect2, varscan2
- SH3PXD2A | c.1646G>A p.R549Q (on ENST00000369774 / NM_001365079.1; = p.R521Q on NM_014631.2) | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs777092853, COSV60118302; called by muse, mutect2, varscan2
- SI | c.4804G>T p.A1602S | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.158); catalogued as COSV52294142; called by muse, mutect2, varscan2
- SIDT2 | c.1872G>C p.V624= | Splice Region (SNP) | VAF 100/136 reads (74%) | catalogued as COSV54059682; called by muse, mutect2, varscan2
- SIPA1L3 | c.3710G>A p.G1237E | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs764236428, COSV55921646; called by muse, mutect2, varscan2
- SLC12A6 | c.3005G>A p.R1002Q (on ENST00000354181 / NM_001365088.1; = p.R951Q on NM_005135.2) | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs778685963, COSV51629531; called by muse, mutect2, varscan2
- SLC25A3 | c.595A>T p.T199S (on ENST00000228318 / NM_005888.3; = p.T198S on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.254); catalogued as rs754743636, COSV51847160; called by muse, mutect2, varscan2
- SLC25A5 | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 301/602 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as rs755053633, COSV58625536, COSV58629168; called by muse, mutect2, varscan2
- SLC38A8 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV55308865; called by muse, mutect2, varscan2
- SLC66A3 | c.267C>A p.N89K | Missense Mutation (SNP) | VAF 105/199 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV54468041; called by muse, mutect2, varscan2
- SMS | c.453A>T p.K151N | Missense Mutation (SNP) | VAF 15/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65114915; called by muse, mutect2
- SNAP91 | c.783A>T p.K261N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52130635; called by muse, mutect2, varscan2
- SNX7 | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 115/133 reads (86%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as COSV60271018; called by muse, mutect2, varscan2
- SPECC1L | c.3008C>T p.S1003L | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV58660289, COSV58660732; called by muse, mutect2, varscan2
- SPSB3 | c.450C>A p.F150L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51907878; called by muse, mutect2, varscan2
- SRSF10 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT tolerated (0.82); PolyPhen benign (0.184); catalogued as rs772353036; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 83/98 reads (85%) | PolyPhen benign (0); catalogued as COSV50078434; called by muse, mutect2, varscan2
- STARD4 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.972); catalogued as COSV56968842; called by muse, mutect2, varscan2
- STN1 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 101/182 reads (55%) | catalogued as COSV56545705; called by muse, varscan2
- SUGP1 | c.887+2T>A p.X296_splice | Splice Site (SNP) | VAF 84/284 reads (30%) | catalogued as COSV55923372; called by muse, mutect2
- SULT1C3 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 69/118 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61254314; called by muse, mutect2, varscan2
- SVIL | c.3332C>T p.T1111M (on ENST00000355867 / NM_021738.3; = p.T685M on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs754799636, COSV63446751; called by muse, mutect2
- TBCK | c.478G>T p.E160* (on ENST00000273980 / NM_001163436.4; = p.E97* on NM_033115.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/106 reads (33%) | catalogued as COSV56760790; called by muse, mutect2, varscan2
- TEX11 | c.1480C>T p.Q494* (on ENST00000344304; = p.Q479* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 8/140 reads (6%) | catalogued as COSV60236539; called by muse, mutect2
- TEX15 | c.1895G>T p.S632I (on ENST00000256246; = p.S1015I on NM_001350162.2) | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1413458735, COSV56351716; called by muse, mutect2, varscan2
- THBS2 | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 27/163 reads (17%) | catalogued as rs1314889912, COSV64681371, COSV64682224; called by muse, mutect2, varscan2
- TLCD3B | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV54227883; called by muse, mutect2, varscan2
- TMC2 | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62656942; called by muse, mutect2
- TMC4 | c.2134C>G p.L712V (on ENST00000617472 / NM_001145303.3; = p.L706V on NM_144686.4) | Missense Mutation (SNP) | VAF 46/403 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs782573312, COSV55366855; called by muse, mutect2, varscan2
- TMPRSS11F | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as rs377605520; called by muse, mutect2, varscan2
- TMPRSS15 | c.2528T>A p.L843Q | Missense Mutation (SNP) | VAF 123/358 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53046065; called by muse, mutect2, varscan2
- TNIK | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV52691640; called by muse, mutect2, varscan2
- TOMM22 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 60/411 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV53266058; called by muse, mutect2, varscan2
- TOX3 | c.1117C>G p.Q373E | Missense Mutation (SNP) | VAF 106/329 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as rs745322355, COSV54871551; called by muse, mutect2, varscan2
- TRBV27 | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as rs746170629; called by muse, mutect2, varscan2
- TRIM39 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV64956262; called by muse, mutect2, varscan2
- TRIML1 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 162/229 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60196218; called by muse, mutect2, varscan2
- TRPC1 | c.958G>T p.E320* (on ENST00000476941 / NM_001251845.2; = p.E286* on NM_003304.4) | Nonsense Mutation (SNP) | VAF 54/216 reads (25%) | catalogued as COSV56428802; called by muse, mutect2, varscan2
- TTN | c.97517G>T p.G32506V (on ENST00000591111; = p.G25082V on NM_003319.4) | Missense Mutation (SNP) | VAF 50/211 reads (24%) | PolyPhen benign (0.001); catalogued as COSV60258109; called by muse, mutect2, varscan2
- TTN | c.85823C>T p.P28608L (on ENST00000591111; = p.P21184L on NM_003319.4) | Missense Mutation (SNP) | VAF 200/367 reads (54%) | PolyPhen probably damaging (0.999); catalogued as COSV60258238; called by muse, mutect2, varscan2
- TTN | c.35266G>C p.E11756Q (on ENST00000591111; = p.E10829Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | PolyPhen benign (0.005); catalogued as COSV60258307; called by muse, mutect2, varscan2
- UGT1A10 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs139087628; called by muse, mutect2
- ULK2 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV64447668; called by muse, mutect2, varscan2
- UPF3B | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52231117; called by muse, mutect2, varscan2
- USH2A | c.11661G>T p.W3887C | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56415524; called by muse, mutect2, varscan2
- USP29 | c.57G>C p.M19I | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV54242086; called by muse, mutect2, varscan2
- USP34 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV68404702; called by muse, mutect2, varscan2
- USP6 | c.3734G>A p.R1245Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.06); catalogued as rs761581553, COSV51472892, COSV51492460; called by muse, varscan2
- VAC14 | c.152A>T p.H51L | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV55756648; called by muse, mutect2, varscan2
- VPS8 | c.1768C>A p.L590M (on ENST00000625842 / NM_001349294.1; = p.L588M on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV54993510, COSV54995560; called by muse, mutect2, varscan2
- VWA8 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55702451; called by muse, mutect2, varscan2
- WIPF1 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV55818947; called by muse, mutect2, varscan2
- WIPF2 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV60275235; called by muse, mutect2, varscan2
- XAB2 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 85/137 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs747797751, COSV50333790; called by muse, mutect2, varscan2
- XIRP2 | c.7987G>T p.E2663* (on ENST00000628543; = p.E2838* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 8/208 reads (4%) | catalogued as COSV54687438, COSV99746734; called by muse, mutect2
- ZAP70 | c.1139C>A p.T380K | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53856361; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1275G>C p.Q425H | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as COSV57639735; called by muse, mutect2, varscan2
- ZNF106 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV55520454; called by muse, mutect2
- ZNF184 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 109/127 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53005216; called by muse, mutect2, varscan2
- ZNF184 | c.1522G>A p.G508R | Missense Mutation (SNP) | VAF 111/128 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV53005226; called by muse, mutect2, varscan2
- ZNF236 | c.2557G>T p.A853S | Missense Mutation (SNP) | VAF 135/286 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV53494723; called by muse, mutect2, varscan2
- ZNF275 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.44); catalogued as COSV64705183; called by muse, mutect2
- ZNF420 | c.1314G>C p.Q438H | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV58495617; called by muse, mutect2, varscan2
- ZNF420 | c.1902G>C p.Q634H | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58495622; called by muse, mutect2, varscan2
- ZNF423 | c.2307G>T p.K769N (on ENST00000563137 / NM_001379286.1; = p.K761N on NM_015069.4) | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV52200344; called by muse, mutect2, varscan2
- ZNF43 | c.2201A>C p.Y734S | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61685310; called by muse, mutect2, varscan2
- ZNF483 | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV58516758; called by muse, mutect2
- ZNF536 | c.2122G>T p.G708W | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62827399, COSV62831324; called by muse, mutect2, varscan2
- ZNF547 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 32/827 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56581608; called by muse, mutect2
- ZNF554 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57886714; called by muse, mutect2
- ZNF614 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 89/684 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as rs1192118002, COSV54545137; called by muse, mutect2, varscan2
- ZNF622 | c.1013A>T p.D338V | Missense Mutation (SNP) | VAF 110/476 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs751439032, COSV58074947; called by muse, mutect2, varscan2
- ZNF765 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV67183165; called by muse, mutect2
- ZNF823 | c.728C>T p.T243M (on ENST00000341191 / NM_001297610.2; = p.T199M on NM_017507.2) | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375817352; called by muse, mutect2
- ZNF831 | c.3442C>G p.P1148A | Missense Mutation (SNP) | VAF 71/98 reads (72%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV64043788; called by muse, mutect2, varscan2
- ZPLD1 | c.774C>A p.D258E (on ENST00000466937 / NM_001329788.1; = p.D274E on NM_175056.2) | Missense Mutation (SNP) | VAF 124/235 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as COSV60355459, COSV60356161; called by muse, mutect2, varscan2
- IGKV1D-42 | c.230A>C p.H77P | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.10108dup p.Q3370Pfs*53 | Frame Shift Ins (INS) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- PCDHGA8 | c.1694_1695delinsT p.P565Lfs*24 | Frame Shift Del (DEL) | VAF 77/227 reads (34%) | called by pindel, varscan2*
- PCIF1 | c.2053del p.E685Rfs*33 | Frame Shift Del (DEL) | VAF 41/65 reads (63%) | called by mutect2, pindel, varscan2
- REG3A | c.205del p.Q69Rfs*24 | Frame Shift Del (DEL) | VAF 55/107 reads (51%) | called by mutect2, varscan2
- SPATA31A1 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 227/760 reads (30%) | called by muse, mutect2, varscan2
- TRBV24-1 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TTN | c.44678del p.G14893Efs*11 (on ENST00000591111; = p.G7469Efs*11 on NM_003319.4) | Frame Shift Del (DEL) | VAF 47/103 reads (46%) | called by mutect2, pindel, varscan2
- ACOX2 | c.1131C>T p.N377= | Silent (SNP) | VAF 56/73 reads (77%) | catalogued as COSV57150290; called by muse, mutect2, varscan2
- AGT | c.1347T>A p.P449= | Silent (SNP) | VAF 101/250 reads (40%) | catalogued as COSV64185259; called by muse, mutect2, varscan2
- AHCTF1 | c.633A>G p.S211= (on ENST00000366508; = p.S185= on NM_015446.5) | Silent (SNP) | VAF 66/155 reads (43%) | catalogued as rs780758041, COSV58253598; called by muse, mutect2, varscan2
- ARHGAP5 | c.4508G>A p.*1503= (on ENST00000345122 / NM_001030055.2; = p.*1502= on NM_001173.3) | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV53735523; called by muse, mutect2, varscan2
- ARHGEF26 | c.1629A>G p.L543= | Silent (SNP) | VAF 51/96 reads (53%) | catalogued as rs1415204513, COSV62850289; called by muse, mutect2, varscan2
- ASXL1 | c.858C>T p.F286= | Silent (SNP) | VAF 115/485 reads (24%) | catalogued as COSV60117269; called by muse, mutect2, varscan2
- ASXL1 | c.2071C>T p.L691= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV60117286; called by muse, mutect2, varscan2
- BMS1 | c.3072G>A p.V1024= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as COSV65735015; called by muse, mutect2, varscan2
- C19orf12 | c.93G>A p.K31= (on ENST00000392278 / NM_001031726.3; = p.K20= on NM_031448.6) | Silent (SNP) | VAF 13/245 reads (5%) | catalogued as COSV60365505; called by muse, mutect2
- C1orf131 | c.333C>T p.I111= | Silent (SNP) | VAF 67/185 reads (36%) | catalogued as COSV59642942; called by muse, mutect2, varscan2
- CADM1 | c.531C>T p.I177= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV59002367, COSV59019384; called by muse, mutect2, varscan2
- CEMIP2 | c.2112C>G p.L704= | Silent (SNP) | VAF 63/188 reads (34%) | catalogued as COSV65488773; called by muse, mutect2, varscan2
- CHIA | c.249G>A p.L83= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100588666, COSV58477377; called by muse, mutect2, varscan2
- CNTN2 | c.1263G>T p.L421= | Silent (SNP) | VAF 250/552 reads (45%) | catalogued as COSV59352086; called by muse, mutect2, varscan2
- DCAF12L2 | c.1140G>A p.Q380= | Silent (SNP) | VAF 15/368 reads (4%) | catalogued as rs1435857471, COSV100758566; called by muse, mutect2
- DDR2 | c.1986C>T p.L662= | Silent (SNP) | VAF 56/354 reads (16%) | catalogued as COSV63369336, COSV63373392; called by muse, mutect2, varscan2
- EFCAB5 | c.711G>A p.L237= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV57934836; called by muse, mutect2, varscan2
- ENPEP | c.2463T>C p.Y821= | Silent (SNP) | VAF 89/104 reads (86%) | catalogued as rs776616806, COSV54455723; called by muse, mutect2, varscan2
- FAM169A | c.1560G>A p.K520= | Silent (SNP) | VAF 155/188 reads (82%) | catalogued as COSV63064073; called by muse, mutect2, varscan2
- FGF12 | c.213A>G p.K71= (on ENST00000454309 / NM_021032.5; = p.K9= on NM_004113.6) | Silent (SNP) | VAF 63/337 reads (19%) | catalogued as COSV53182269; called by muse, mutect2, varscan2
- FOXD4L5 | c.828C>A p.P276= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs1311805938, COSV101073114; called by mutect2, varscan2
- GALNT17 | c.1383T>C p.N461= | Silent (SNP) | VAF 147/554 reads (27%) | catalogued as COSV61182185; called by muse, mutect2, varscan2
- GCC1 | c.1932A>G p.Q644= | Silent (SNP) | VAF 105/174 reads (60%) | catalogued as COSV58463487; called by muse, mutect2, varscan2
- GIMAP6 | c.630C>T p.A210= | Silent (SNP) | VAF 256/394 reads (65%) | catalogued as COSV61034415; called by muse, mutect2, varscan2
- GOT1 | c.63C>A p.L21= | Silent (SNP) | VAF 12/200 reads (6%) | catalogued as COSV65147758; called by muse, mutect2
- GPAA1 | c.438C>G p.L146= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV60156323; called by muse, mutect2, varscan2
- GPC3 | c.1065C>A p.R355= | Silent (SNP) | VAF 140/376 reads (37%) | catalogued as COSV63669765; called by muse, mutect2, varscan2
- GRIK3 | c.1077C>T p.G359= | Silent (SNP) | VAF 205/328 reads (63%) | catalogued as rs1195514120, COSV66143496; called by muse, mutect2, varscan2
- HCN1 | c.1290G>A p.K430= | Silent (SNP) | VAF 41/337 reads (12%) | catalogued as COSV57510927, COSV57529983; called by muse, mutect2, varscan2
- HIP1 | c.2916G>T p.T972= | Silent (SNP) | VAF 228/360 reads (63%) | catalogued as rs375211454, COSV61190012; called by muse, mutect2, varscan2
- IGKV3D-20 | c.39C>A p.L13= | Silent (SNP) | VAF 64/239 reads (27%) | called by muse, mutect2, varscan2
- IGSF1 | c.963C>A p.P321= | Silent (SNP) | VAF 70/156 reads (45%) | catalogued as COSV63839326; called by muse, mutect2, varscan2
- IPO8 | c.1971C>T p.S657= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV56244511; called by muse, mutect2, varscan2
- JCAD | c.1389G>C p.P463= | Silent (SNP) | VAF 49/221 reads (22%) | catalogued as COSV64761159; called by muse, mutect2, varscan2
- KLK3 | c.315C>G p.L105= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV58102153; called by muse, mutect2, varscan2
- LILRB1 | c.348G>A p.K116= (on ENST00000427581; = p.K80= on NM_006669.6) | Silent (SNP) | VAF 132/528 reads (25%) | catalogued as COSV61120894, COSV99048729; called by muse, mutect2, varscan2
- LMNA | c.216C>A p.R72= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV61543719; called by muse, mutect2, varscan2
- LYG2 | c.103C>T p.L35= | Silent (SNP) | VAF 127/228 reads (56%) | catalogued as COSV60716421; called by muse, mutect2, varscan2
- MAFF | c.33A>G p.L11= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as COSV58299562; called by muse, varscan2
- MAP2 | c.2487C>T p.A829= | Silent (SNP) | VAF 125/204 reads (61%) | catalogued as COSV52303341; called by muse, mutect2, varscan2
- MUC17 | c.9882C>G p.A3294= | Silent (SNP) | VAF 402/685 reads (59%) | catalogued as COSV60299106; called by muse, mutect2
- MUC4 | c.16215G>T p.L5405= (on ENST00000463781 / NM_018406.7; = p.L1169= on NM_004532.6) | Silent (SNP) | VAF 30/423 reads (7%) | catalogued as COSV57796718; called by muse, mutect2
- MVB12A | c.138C>T p.F46= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV57679523; called by muse, mutect2
- MYT1L | c.2479C>A p.R827= | Silent (SNP) | VAF 98/162 reads (60%) | catalogued as COSV67720706, COSV67728880; called by muse, mutect2, varscan2
- NEB | c.1407C>T p.G469= | Silent (SNP) | VAF 58/186 reads (31%) | catalogued as COSV51446274; called by muse, mutect2, varscan2
- NOLC1 | c.1251G>C p.L417= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV64180933; called by muse, mutect2, varscan2
- NOLC1 | c.1803G>A p.K601= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs781474264, COSV64180940, COSV64181120; called by muse, mutect2, varscan2
- NOLC1 | c.1986G>A p.L662= | Silent (SNP) | VAF 123/495 reads (25%) | catalogued as COSV64180945; called by muse, varscan2
- NOTCH3 | c.4986C>G p.V1662= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV54644556; called by muse, varscan2
- NPBWR2 | c.597G>C p.L199= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV63900477; called by muse, mutect2, varscan2
- OGDH | c.2334G>T p.L778= | Silent (SNP) | VAF 83/97 reads (86%) | catalogued as COSV56055190; called by muse, mutect2, varscan2
- OR2G6 | c.874C>T p.L292= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs1171998356, COSV58575515; called by muse, mutect2
- OR2M5 | c.81C>T p.L27= | Silent (SNP) | VAF 22/802 reads (3%) | catalogued as COSV63546817; called by muse, mutect2
- OR52N5 | c.858G>T p.V286= | Silent (SNP) | VAF 85/101 reads (84%) | catalogued as COSV57699314; called by muse, mutect2, varscan2
- OR8B4 | c.111C>T p.F37= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV62070313; called by muse, mutect2, varscan2
- PAK5 | c.2037G>A p.L679= | Silent (SNP) | VAF 79/557 reads (14%) | catalogued as COSV62034813; called by muse, mutect2, varscan2
- PAXIP1 | c.2097C>T p.F699= | Silent (SNP) | VAF 31/162 reads (19%) | catalogued as COSV68187288; called by muse, mutect2, varscan2
- PCDHGC5 | c.2253G>C p.V751= | Silent (SNP) | VAF 4/96 reads (4%) | catalogued as COSV52762936; called by muse, mutect2
- PDSS2 | c.280C>T p.L94= | Silent (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- PEX1 | c.1221C>G p.L407= | Silent (SNP) | VAF 46/363 reads (13%) | catalogued as COSV50411057, COSV99951954; called by muse, mutect2, varscan2
- PEX5L | c.1293G>A p.V431= | Silent (SNP) | VAF 24/615 reads (4%) | catalogued as COSV55853501; called by muse, mutect2
- PKD1L2 | c.2820C>G p.T940= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV55167978; called by muse, mutect2, varscan2
- PKHD1 | c.8292C>T p.L2764= | Silent (SNP) | VAF 46/193 reads (24%) | catalogued as rs756431455, COSV61890036; called by muse, mutect2, varscan2
- PLCE1 | c.4626A>G p.L1542= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV53365524; called by muse, mutect2, varscan2
- PLCH1 | c.2724A>C p.V908= (on ENST00000340059 / NM_001130960.2; = p.V900= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/279 reads (22%) | catalogued as COSV58207260, COSV58207311; called by muse, mutect2, varscan2
- PLEKHA6 | c.2244C>A p.I748= | Silent (SNP) | VAF 33/255 reads (13%) | catalogued as COSV55332294, COSV55338644; called by muse, mutect2, varscan2
- PLXNA1 | c.1824C>T p.S608= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs1213408179, COSV52531053; called by muse, mutect2, varscan2
- PLXNA4 | c.3126C>T p.I1042= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as rs772829574, COSV58111958; called by muse, mutect2
- POLR1A | c.3594G>C p.L1198= | Silent (SNP) | VAF 4/88 reads (5%) | catalogued as COSV55689628, COSV55697639; called by muse, mutect2
- PPFIA2 | c.477G>C p.R159= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100333546, COSV61047701; called by muse, mutect2, varscan2
- PRDM13 | c.1446C>G p.L482= | Silent (SNP) | VAF 56/66 reads (85%) | catalogued as COSV65030508; called by muse, mutect2, varscan2
- PRPF40B | c.1018C>A p.R340= (on ENST00000380281; = p.R334= on NM_012272.3) | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV56061125, COSV99979152; called by muse, mutect2, varscan2
- PSPH | c.603C>T p.I201= | Silent (SNP) | VAF 16/189 reads (8%) | catalogued as rs763944186, COSV51912750; called by muse, mutect2
- PTPRO | c.3594G>A p.K1198= (on ENST00000281171 / NM_030667.3; = p.K1170= on NM_002848.4) | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV55506269; called by muse, mutect2, varscan2
- PXMP4 | c.330C>T p.L110= | Silent (SNP) | VAF 42/319 reads (13%) | catalogued as COSV54133980; called by muse, mutect2, varscan2
- RALGAPA1 | c.3573C>T p.I1191= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV51892851; called by muse, mutect2, varscan2
- RBM48 | c.1035A>T p.P345= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV56003417; called by muse, mutect2, varscan2
- RGS22 | c.1962T>G p.G654= | Silent (SNP) | VAF 72/120 reads (60%) | catalogued as COSV62665928; called by muse, mutect2, varscan2
- RPL23A | c.114G>A p.K38= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as COSV52644975; called by muse, mutect2, varscan2
- SCN2A | c.489A>G p.T163= | Silent (SNP) | VAF 57/238 reads (24%) | catalogued as rs1057520898, COSV51851800; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIGLEC14 | c.786G>T p.V262= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV55782516; called by muse, mutect2, varscan2
- SLC44A4 | c.1437C>G p.P479= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs1477664053, COSV57668703; called by muse, mutect2, varscan2
- SLC4A11 | c.1206C>T p.D402= | Silent (SNP) | VAF 82/179 reads (46%) | catalogued as rs764910925, COSV66263357; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC4A1AP | c.1614G>A p.A538= | Silent (SNP) | VAF 62/210 reads (30%) | catalogued as rs116617546, COSV58136873; called by muse, mutect2, varscan2
- STAB2 | c.4050G>A p.G1350= | Silent (SNP) | VAF 58/114 reads (51%) | catalogued as COSV66344523; called by muse, mutect2
- TCTEX1D1 | c.420G>A p.Q140= | Silent (SNP) | VAF 152/265 reads (57%) | catalogued as COSV51076572; called by muse, mutect2, varscan2
- TESK1 | c.903T>A p.R301= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as COSV52412115; called by muse, mutect2, varscan2
- TESK2 | c.324C>G p.L108= | Silent (SNP) | VAF 20/752 reads (3%) | catalogued as COSV59149937, COSV59156172; called by muse, mutect2
- THOC2 | c.195G>A p.Q65= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV55553217; called by muse, mutect2, varscan2
- TONSL | c.1546C>A p.R516= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV68049061; called by muse, mutect2, varscan2
- TTN | c.51276C>G p.L17092= (on ENST00000591111; = p.L9668= on NM_003319.4) | Silent (SNP) | VAF 32/346 reads (9%) | catalogued as rs766306616, COSV59989551; called by muse, mutect2
- VANGL2 | c.1287G>C p.T429= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs572362079, COSV63605162; called by muse, mutect2, varscan2
- XRCC6 | c.855A>C p.P285= | Silent (SNP) | VAF 150/410 reads (37%) | catalogued as COSV63158771; called by muse, varscan2
- ZAP70 | c.555C>A p.G185= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV53856351; called by muse, mutect2, varscan2
- ZEB1 | c.2106A>G p.T702= | Silent (SNP) | VAF 109/174 reads (63%) | catalogued as COSV58051594; called by muse, mutect2, varscan2
- ZNF28 | c.1932C>T p.F644= | Silent (SNP) | VAF 20/702 reads (3%) | catalogued as COSV60421532; called by muse, mutect2
- ZNF441 | c.1620C>T p.F540= | Silent (SNP) | VAF 60/99 reads (61%) | catalogued as COSV63540581; called by muse, mutect2, varscan2
- ZNF816 | c.405G>A p.L135= | Silent (SNP) | VAF 30/767 reads (4%) | catalogued as rs529254404, COSV54410345, COSV54412072; called by muse, mutect2
- GABRA3 | c.-1G>A | 5'UTR (SNP) | VAF 14/290 reads (5%) | catalogued as COSV100942626; called by muse, mutect2
- MIRLET7C | n.81G>C | RNA (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- NRP1 | c.981+4533A>G | Intron (SNP) | VAF 26/43 reads (60%) | called by mutect2, varscan2
- NTRK3 | c.1586-40598C>G | Intron (SNP) | VAF 8/210 reads (4%) | catalogued as COSV100446338; called by muse, mutect2
- SEPTIN9 | c.722-6272C>G | Intron (SNP) | VAF 29/122 reads (24%) | catalogued as rs1020983150, COSV100218094, COSV61211830; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15171G>T | Intron (SNP) | VAF 43/202 reads (21%) | catalogued as COSV67448021; called by muse, mutect2, varscan2
- TRIM36 | c.64-7423G>A | Intron (SNP) | VAF 43/144 reads (30%) | catalogued as COSV99142343; called by muse, mutect2, varscan2
- TTN | c.34264+558dup | Intron (INS) | VAF 121/476 reads (25%) | called by mutect2, varscan2
